Gene-level copy-number profile of tumor specimen TCGA-ZN-A9VS-01A from TCGA case TCGA-ZN-A9VS, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 67.0 years (24,490 days).
Specimen TCGA-ZN-A9VS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.a6ffd12d-1572-404d-8922-09a8f4ee1bca.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ZN-A9VS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/69ade9ef-77e9-44f5-9a31-2c9eaeb3c9b6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 7,038; copy number 3: 9,511; copy number 4: 41,085; copy number 5: 2,073; copy number 6: 106.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ZN-A9VS-01A-11D-A39Q-01): tumor purity 0.5, ploidy 3.69, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
